Gene-level copy-number profile of tumor specimen TCGA-CN-4742-01A from TCGA case TCGA-CN-4742, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tongue, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G3; Age at diagnosis: 48.7 years (17,793 days).
Specimen TCGA-CN-4742-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.213e2fd8-50e8-46b0-bcb8-9ba6d2970967.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CN-4742-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/4ec24fbe-8c3f-41a1-963d-7025129052cc

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 2; copy number 2: 10,331; copy number 3: 28,192; copy number 4: 17,408; copy number 5: 826; copy number 6: 2,386; copy number 7: 409; copy number 8: 11; copy number 9: 9; copy number 11: 45; copy number 12: 28; copy number 15: 86; copy number 23: 21; copy number 31: 10; copy number 38: 42; copy number 67: 9.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CN-4742-01A-02D-1510-01): tumor purity 0.3, ploidy 3.29, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 2 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:109,511,475–109,534,332, 2 genes: MIR3927, YBX1P6.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 656 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:72,280,969–75,101,943, 51 genes, copy number 7 (within-gene range 4–7): ADAMTS3, AC095056.1, HNRNPA1P67, RNU4ATAC9P, RNU6ATAC5P, COX18, ANKRD17, HMGA1P2, AC053527.2, AC053527.1, AC108157.1, ALB, AFP, AFM, LINC02499, AC074250.1, RASSF6, UMLILO, CXCL8, AC112518.1, CXCL6, PPBPP1, PF4V1, CXCL1, HNRNPA1P55, CXCL1P1, PF4, PPBP, CXCL5, AC097709.1, RN7SL218P, CXCL3, PPBPP2, AC093677.3, AC093677.1, CXCL2, MTHFD2L, AC093677.2, EPGN, EREG, AC021180.1, AREG, AC239584.1, BTC, AC098825.1, HSPE1P23, PARM1, PARM1-AS1, AC110760.1, LINC02562, AC110760.2.
- chr5:9,498,401–9,903,852, 11 genes, copy number 8: AC027335.2, SEMA5A-AS1, AC027335.1, SNHG18, SNORD123, AC026787.1, TAS2R1, LINC02112, RNA5SP177, AC091838.1, LINC02221.
- chr8:48,193,850–49,352,844, 23 genes, copy number 7–67: AC104989.1, IDI1P2, RNU6-295P, RNA5SP531, RPL29P19, AC041040.1, AC026904.1, AC026904.2, AC022915.2, LINC02599, LINC02847, AC022915.1, AC022915.3, EFCAB1, AC100805.1, AC013701.1, SNAI2, AC013701.2, AC044893.2, PPDPFL, AC044893.1, RN7SKP294, RFPL4AP7.
- chr11:43,311,963–50,422,316, 224 genes, copy number 7–15 (broad region; genes not listed).
- chr11:69,072,915–69,162,440, 1 gene, copy number 38 (within-gene range 5–38): AP003071.5.
- chr11:69,147,228–72,479,237, 113 genes, copy number 7–38 (broad region; genes not listed).
- chr18:60,329,190–60,902,726, 9 genes, copy number 9 (within-gene range 2–9): AC091576.1, MC4R, AC010928.2, MRPS5P4, AC010928.3, AC010928.1, AC113137.1, CTBP2P3, HMGN1P31.
- chr20:7,069,614–22,074,654, 224 genes, copy number 7–23 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
